Somatic mutation profile of tumor specimen TARGET-30-PATSKE-01A (aliquot TARGET-30-PATSKE-01A-01D) from TARGET case TARGET-30-PATSKE, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Spinal meninges; Age at diagnosis: 11.7 years (4,285 days).
Specimen TARGET-30-PATSKE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2629acb2-74db-4946-a767-9a601f309c5d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATSKE-10A (Blood Derived Normal), aliquot TARGET-30-PATSKE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51eb7d99-6d86-4ae7-9306-3b2604f3244f

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 2, 3'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFAT5 | c.1168T>A p.L390M | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63034377; called by muse, mutect2, varscan2
- CNTN5 | c.*1867C>A | 3'UTR (SNP) | VAF 51/122 reads (42%) | catalogued as rs768880433, COSV54372198; called by muse, mutect2, varscan2
- HOXB3 | c.-571T>A | 5'UTR (SNP) | VAF 32/252 reads (13%) | catalogued as rs569661454; called by muse, varscan2
- REV3L | c.-335C>G | 5'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
